Somatic mutation profile of tumor specimen TARGET-10-PARMWZ-09A (aliquot TARGET-10-PARMWZ-09A-01D) from TARGET case TARGET-10-PARMWZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,700 days).
Specimen TARGET-10-PARMWZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 298f1561-9936-484e-ae01-8581cbf8f24b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMWZ-14A (Bone Marrow Normal), aliquot TARGET-10-PARMWZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9856923e-b8ec-4e12-9753-059fd3499010

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 2, Frame Shift Ins 2, Nonsense Mutation 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTR9 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 55/58 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs869312709, COSV63727939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.3130C>T p.R1044* (on ENST00000367255 / NM_182961.4; = p.R1051* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 42/65 reads (65%) | catalogued as rs757719808, COSV54920772, COSV54924065; called by muse, mutect2, varscan2
- TMEM94 | c.657dup p.F220Lfs*28 | Frame Shift Ins (INS) | VAF 14/26 reads (54%) | catalogued as rs753764149; called by mutect2, varscan2
- NF1 | c.3282dup p.L1095Ifs*11 | Frame Shift Ins (INS) | VAF 29/39 reads (74%) | called by mutect2, pindel, varscan2
- DMD | c.5235C>T p.R1745= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as rs766312119, COSV63794796; called by muse, mutect2, varscan2
- ASB17 | c.-13G>A | 5'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TFAP2D | c.-99_-66delinsCCTTTAAAAATTGGAAAATACAAGAAGTTTGGAT | 5'UTR (ONP) | VAF 14/102 reads (14%) | called by pindel, varscan2*
